Somatic mutation profile of tumor specimen MMRF_1556_1_BM_CD138pos (aliquot MMRF_1556_1_BM_CD138pos_T1_KBS5U_L03001) from MMRF case MMRF_1556, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 71.6 years (26,148 days).
Specimen MMRF_1556_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a49b396f-576c-4a17-b404-577f76ff8d8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1556_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1556_1_PB_Whole_C3_KBS5U_L03009; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a469c5d-dd43-4982-84bb-a6ad92740697

The open-access MAF lists 36 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 5, 5'Flank 4, RNA 3, Nonsense Mutation 3, 3'Flank 2, Intron 2, 3'UTR 2, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C15orf39 | c.508G>A p.A170T | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.045); catalogued as COSV62297240; called by muse, mutect2, varscan2
- CAMK2A | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 34/71 reads (48%) | catalogued as rs751885208, COSV62247430; called by muse, mutect2, varscan2
- HSPA8 | c.1121-1G>A p.X374_splice | Splice Site (SNP) | VAF 80/192 reads (42%) | catalogued as rs1271757393; called by muse, mutect2, varscan2
- IGHV2-70 | c.289A>C p.N97H | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs368209907; called by muse, varscan2
- IGHV2-70 | c.256A>C p.T86P | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as rs757180345; called by muse, varscan2
- IGHV2-70 | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs369066675; called by muse, varscan2
- IGHV2-70 | c.218A>G p.D73G | Missense Mutation (SNP) | VAF 41/78 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.162); catalogued as rs184814603; called by muse, varscan2
- IGLV4-60 | c.176A>C p.Q59P | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751662182, COSV66503790; called by muse, mutect2, varscan2
- PLCL1 | c.2149G>T p.G717W | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70821662; called by muse, mutect2, varscan2
- PTGER3 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs926187292, COSV100138364, COSV60689639; called by muse, varscan2
- SI | c.5371G>A p.G1791R | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs753703386, COSV100014451; called by muse, mutect2
- CEP170 | c.2984G>T p.R995L | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- CREB3 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- MAN2A2 | c.1521T>G p.Y507* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- MSR1 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC17 | c.691T>C p.S231P | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- ADGRB3 | c.2403G>A p.S801= | Silent (SNP) | VAF 95/205 reads (46%) | catalogued as rs773510249, COSV65390306; called by muse, mutect2, varscan2
- DSG4 | c.783C>T p.D261= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs771033904; called by muse, mutect2, varscan2
- IGHV3-21 | c.303A>G p.Q101= | Silent (SNP) | VAF 48/146 reads (33%) | catalogued as rs782438435; called by muse, varscan2
- IGLC2 | c.276A>G p.E92= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as rs773052695; called by muse, mutect2, varscan2
- ZBTB39 | c.2082G>A p.E694= | Silent (SNP) | VAF 4/83 reads (5%) | called by muse, mutect2
- AL353804.7 | chrX:73852011 del A | 3'Flank (DEL) | VAF 64/77 reads (83%) | catalogued as rs200290800; called by mutect2, varscan2
- ARID1B | c.3511+1741C>T | Intron (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021303 C>T | 5'Flank (SNP) | VAF 42/82 reads (51%) | catalogued as rs563776606; called by muse, mutect2, varscan2
- CEP170P1 | n.2786G>T | RNA (SNP) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- HEXA | chr15:72376465 G>T | 5'Flank (SNP) | VAF 32/77 reads (42%) | called by muse, mutect2, varscan2
- IMMT | chr2:86195759 T>C | 5'Flank (SNP) | VAF 24/46 reads (52%) | called by muse, mutect2, varscan2
- INPP4B | chr4:142026890 G>A | 3'Flank (SNP) | VAF 16/50 reads (32%) | catalogued as rs889523941; called by muse, mutect2, varscan2
- LINC02418 | n.1316C>T | RNA (SNP) | VAF 37/79 reads (47%) | catalogued as rs1304636646; called by muse, mutect2, varscan2
- PGRMC2 | chr4:128288375 G>A | 5'Flank (SNP) | VAF 57/109 reads (52%) | called by muse, mutect2, varscan2
- PLPPR4 | c.-177G>A | 5'UTR (SNP) | VAF 24/55 reads (44%) | catalogued as rs1487797746; called by muse, mutect2, varscan2
- RAB11FIP2 | c.*2861C>T | 3'UTR (SNP) | VAF 49/93 reads (53%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.1654_1655insC | RNA (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- TMPRSS4 | c.43+16G>A | Intron (SNP) | VAF 41/75 reads (55%) | called by muse, mutect2
- ZMAT4 | c.*829del | 3'UTR (DEL) | VAF 42/85 reads (49%) | catalogued as rs34653580; called by mutect2, varscan2
